Somatic mutation profile of tumor specimen TCGA-SI-A71Q-01A (aliquot TCGA-SI-A71Q-01A-12D-A33E-09) from TCGA case TCGA-SI-A71Q, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 34.4 years (12,559 days).
Specimen TCGA-SI-A71Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24f4046d-8915-44b1-88c2-d45d174f0587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SI-A71Q-10A (Blood Derived Normal), aliquot TCGA-SI-A71Q-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9b2b4f5-2055-42f0-88aa-16fcdfe69dac

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.3529G>T p.V1177L | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99177124; called by muse, mutect2, varscan2
- ARID1A | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV100251081, COSV61373194; called by muse, mutect2, varscan2
- ARRDC5 | c.1013C>G p.P338R (on ENST00000381781; = p.P324R on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV101108139; called by muse, varscan2
- CASC3 | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 59/106 reads (56%) | catalogued as COSV99229637; called by muse, mutect2, varscan2
- CEACAM5 | c.1720C>T p.Q574* | Nonsense Mutation (SNP) | VAF 62/191 reads (32%) | catalogued as COSV99703843; called by muse, mutect2, varscan2
- DPPA5 | c.23G>C p.R8T | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100951490; called by muse, mutect2, varscan2
- GALNT14 | c.704C>T p.T235I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs370991103; called by muse, mutect2, varscan2
- HACE1 | c.2131G>C p.E711Q | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99493517; called by muse, mutect2, varscan2
- KASH5 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs535323954, COSV101483385; called by muse, mutect2, varscan2
- KLF8 | c.592C>A p.P198T | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV100808195; called by muse, mutect2, varscan2
- MGA | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.889); catalogued as COSV54947841, COSV54962042, COSV99579389; called by muse, mutect2, varscan2
- MTMR8 | c.963T>G p.I321M | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as COSV100878415; called by muse, mutect2, varscan2
- NIN | c.602A>T p.H201L | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99812838; called by muse, mutect2, varscan2
- NRK | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99687292; called by muse, mutect2, varscan2
- PGAP1 | c.2542A>C p.N848H | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100698122; called by muse, mutect2, varscan2
- PTPN4 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357655871, COSV99749953; called by muse, mutect2, varscan2
- SIK3 | c.2813C>T p.S938L (on ENST00000445177 / NM_001366686.2; = p.S896L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs755779340, COSV52611490; called by muse, mutect2, varscan2
- SLC38A8 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV100230403; called by muse, mutect2, varscan2
- ZDBF2 | c.4217G>T p.G1406V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.047); catalogued as rs1284811629, COSV100984613; called by muse, mutect2, varscan2
- BTBD10 | c.329del p.P110Qfs*54 | Frame Shift Del (DEL) | VAF 63/92 reads (68%) | called by mutect2, pindel, varscan2
- ABCC2 | c.3465C>T p.T1155= | Silent (SNP) | VAF 44/72 reads (61%) | catalogued as COSV100966452; called by muse, mutect2, varscan2
- ADGRG4 | c.8748T>C p.V2916= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV54968254; called by muse, mutect2, varscan2
- ARRDC5 | c.945C>A p.I315= (on ENST00000381781; = p.I301= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV101108140; called by muse, varscan2
- CBWD1 | c.993C>T p.V331= | Silent (SNP) | VAF 133/245 reads (54%) | catalogued as COSV100070764; called by muse, mutect2, varscan2
- CD2AP | c.1515C>T p.F505= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100830392; called by muse, mutect2, varscan2
- DGKI | c.3030G>T p.V1010= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs1562992696, COSV99933449, COSV99935993; called by muse, mutect2, varscan2
- LCP1 | c.1350G>A p.L450= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as rs886192736, COSV100549817; called by muse, mutect2, varscan2
- OR11A1 | c.234A>T p.A78= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV101010696; called by muse, mutect2, varscan2
- TYK2 | c.3192C>T p.P1064= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV99314545; called by muse, mutect2, varscan2
- VWA3B | c.3258C>T p.G1086= | Silent (SNP) | VAF 60/111 reads (54%) | catalogued as rs752586602, COSV69034129; called by muse, mutect2, varscan2
